CCDI case PBBYAE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1d623431-913b-444f-a057-934be4505052

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9473/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.2 years (1,186 days).

Biospecimens (3 samples)
- Sample 0DKAKM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKAKX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DKAMS: Tissue type: Tumor; Specimen type: Solid Tissue.
